Somatic mutation profile of tumor specimen TCGA-BT-A20J-01A (aliquot TCGA-BT-A20J-01A-11D-A14W-08) from TCGA case TCGA-BT-A20J, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 75.7 years (27,646 days).
Specimen TCGA-BT-A20J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8d78838-650d-4db9-9567-5b4ece3669d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BT-A20J-11A (Solid Tissue Normal), aliquot TCGA-BT-A20J-11A-11D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12dd4299-8a57-4807-82d1-0b0c099aeb8f

The open-access MAF lists 507 somatic variants for this specimen: 371 protein-altering or splice-affecting, 125 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 336, Silent 125, Nonsense Mutation 23, Intron 6, Splice Site 4, RNA 3, 3'UTR 2, Frame Shift Del 2, Nonstop Mutation 2, Splice Region 2, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PRX | c.1390C>T p.R464* | Nonsense Mutation (SNP) | VAF 75/230 reads (33%) | catalogued as rs574861276, COSV52528280; ClinVar: pathogenic; called by muse, varscan2
- SOS1 | c.2536G>A p.E846K | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as rs397517159, CM070272, COSV67673763; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.437G>C p.W146S | Missense Mutation (SNP) | VAF 18/47 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.75); PolyPhen benign (0.13); catalogued as CM107391, COSV52661900, COSV52703354, COSV52753201; called by muse, varscan2
- A2M | c.3409G>C p.E1137Q | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.17); catalogued as COSV59382700; called by muse, mutect2
- ABLIM1 | c.277G>C p.E93Q | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV53299511; called by muse, mutect2, varscan2
- ACAD8 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55538985, COSV55541591; called by muse, mutect2, varscan2
- ACTN4 | c.2552C>T p.S851F | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53142861, COSV53144677; called by muse, mutect2, varscan2
- ADAMTS14 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as rs369181052; called by muse, mutect2, varscan2
- ADAMTS16 | c.1982G>C p.R661T | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV56977608; called by muse, mutect2, varscan2
- AFF3 | c.2680G>A p.E894K | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.3); catalogued as rs781704362, COSV57839916; called by muse, mutect2, varscan2
- AKAP8L | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs775614362, COSV68472785; called by muse, mutect2, varscan2
- ALPK1 | c.3674G>A p.C1225Y | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51581562; called by muse, mutect2, varscan2
- ANKRD27 | c.3130G>C p.E1044Q | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.254); catalogued as rs1428777193, COSV60128779; called by muse, mutect2, varscan2
- ANKZF1 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV60132120; called by muse, mutect2, varscan2
- ANP32E | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 42/402 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV58481327; called by muse, mutect2, varscan2
- ANPEP | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.511); catalogued as COSV55589111; called by muse, mutect2, varscan2
- AOX1 | c.3394G>A p.E1132K | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV53495103; called by muse, mutect2
- APEH | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs761116888; called by muse, mutect2
- APOA5 | c.622G>C p.E208Q | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as COSV57062197; called by muse, mutect2, varscan2
- APPL2 | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV51587985; called by muse, mutect2, varscan2
- APPL2 | c.416-1G>C p.X139_splice | Splice Site (SNP) | VAF 29/192 reads (15%) | catalogued as COSV51588007; called by muse, mutect2, varscan2
- ARHGAP35 | c.3235C>T p.Q1079* | Nonsense Mutation (SNP) | VAF 29/53 reads (55%) | catalogued as COSV68331497; called by muse, mutect2, varscan2
- ARHGAP44 | c.406C>G p.Q136E | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.958); catalogued as COSV52389013; called by muse, mutect2, varscan2
- ARHGAP5 | c.143A>G p.E48G | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV61533830; called by muse, mutect2, varscan2
- ARHGAP5 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61533836; called by muse, mutect2, varscan2
- ASPM | c.1153G>C p.E385Q | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV54124396; called by muse, mutect2, varscan2
- ATG2A | c.4081G>A p.E1361K | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV65965792; called by muse, mutect2, varscan2
- ATP7A | c.1258G>C p.E420Q | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.596); catalogued as COSV58442299; called by muse, mutect2
- ATR | c.6277C>G p.L2093V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.633); catalogued as COSV63383735; called by muse, mutect2, varscan2
- BACH2 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV57584048, COSV99998937; called by muse, mutect2, varscan2
- BANK1 | c.2092C>G p.L698V | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.902); catalogued as COSV59838072; called by muse, mutect2
- BBS5 | c.871G>C p.D291H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as COSV54751827, COSV99751953; called by muse, mutect2, varscan2
- BDH2 | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99600831; called by muse, mutect2
- BMS1 | c.2281G>A p.G761R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs1490654599, COSV65732835; called by muse, mutect2, varscan2
- BOP1 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs376129693; called by muse, mutect2, varscan2
- BRDT | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV62863236; called by muse, mutect2, varscan2
- CACNA2D1 | c.31C>G p.L11V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.899); catalogued as COSV100667286, COSV62372193; called by muse, mutect2
- CAMSAP3 | c.1127C>T p.S376F | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.757); catalogued as rs757268205; called by muse, mutect2
- CAMSAP3 | c.1205C>G p.S402C | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as rs1197394519; called by muse, mutect2
- CAMTA2 | c.1941G>C p.Q647H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61832955; called by muse, mutect2, varscan2
- CAT | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.898); catalogued as rs148918137; called by muse, mutect2, varscan2
- CAVIN1 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.704); catalogued as COSV63811370; called by muse, mutect2, varscan2
- CCDC27 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.212); catalogued as rs370107628, COSV53900827; called by muse, mutect2, varscan2
- CCDC86 | c.894G>T p.K298N | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV57124407; called by muse, mutect2, varscan2
- CCND1 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.301); catalogued as rs749614691, COSV57119088; called by muse, mutect2, varscan2
- CCRL2 | c.517C>G p.Q173E | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.551); catalogued as COSV62193178; called by muse, mutect2, varscan2
- CD163 | c.1250G>A p.G417E | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63129293; called by muse, mutect2, varscan2
- CD1A | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.818); catalogued as rs769686492, COSV56860291; called by muse, mutect2, varscan2
- CD200R1L | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV68003745, COSV68004783; called by muse, mutect2, varscan2
- CD2AP | c.1745C>G p.S582C | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as COSV63759167, COSV63762212; called by muse, mutect2, varscan2
- CDC6 | c.652G>C p.D218H | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV52929765; called by muse, mutect2, varscan2
- CDH26 | c.443C>G p.S148C | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as rs149485584; called by muse, mutect2, varscan2
- CEP131 | c.2767G>A p.E923K (on ENST00000269392 / NM_001319228.2; = p.E920K on NM_014984.4) | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs577025986, COSV53950529; called by muse, mutect2, varscan2
- CERT1 | c.2185G>C p.E729Q (on ENST00000405807 / NM_001130105.1; = p.E601Q on NM_005713.3) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54655330; called by muse, mutect2, varscan2
- CIART | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV51743122; called by muse, mutect2, varscan2
- CLCA1 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV52324922; called by muse, mutect2, varscan2
- CLCA1 | c.2039G>A p.G680E | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.932); catalogued as COSV52324930; called by muse, mutect2
- CNKSR3 | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.228); catalogued as COSV72161660; called by muse, mutect2, varscan2
- CNNM3 | c.1155C>G p.F385L | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV59708644; called by muse, mutect2, varscan2
- COL4A4 | c.2246C>T p.S749L | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV61629456; called by muse, mutect2, varscan2
- COMP | c.1588G>A p.D530N | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs145034923; called by muse, mutect2, varscan2
- COPA | c.871C>A p.H291N | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as COSV54097777; called by muse, mutect2, varscan2
- CPT1A | c.2245C>T p.R749C | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1246687899, COSV55752704; called by muse, mutect2
- CRISPLD1 | c.1431G>C p.Q477H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV51544084, COSV51549453; called by muse, mutect2, varscan2
- CRNKL1 | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55618779, COSV55648983; called by muse, mutect2, varscan2
- CSNK2A1 | c.816C>G p.I272M | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as COSV53933566, COSV53933976; called by muse, mutect2, varscan2
- CUL7 | c.3937G>C p.E1313Q | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); catalogued as CM1210388, COSV54812994; called by muse, mutect2, varscan2
- CYBC1 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.704); catalogued as rs767743543, COSV60062707; called by muse, varscan2
- CYP7A1 | c.774C>G p.S258R | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV56962150; called by muse, mutect2
- DDX19A | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.157); catalogued as COSV56358642; called by muse, mutect2, varscan2
- DDX24 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV58211779; called by muse, mutect2, varscan2
- DDX39B | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.573); catalogued as COSV66018557; called by muse, mutect2, varscan2
- DDX60 | c.1215G>A p.M405I | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as COSV67095007, COSV67099318; called by muse, mutect2, varscan2
- DHRS12 | c.67G>A p.E23K (on ENST00000444610 / NM_001377930.1; = p.M1? on NM_024705.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 87/199 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.389); catalogued as COSV54470344; called by muse, mutect2, varscan2
- DHX34 | c.403C>G p.R135G | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV60894314, COSV60894355; called by muse, mutect2
- DHX8 | c.3333C>G p.F1111L | Missense Mutation (SNP) | VAF 87/144 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52250898, COSV52253922; called by muse, mutect2, varscan2
- DMTN | c.331C>T p.Q111* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as COSV56113935; called by muse, mutect2, varscan2
- DNAH3 | c.4041C>T p.A1347= | Splice Region (SNP) | VAF 21/68 reads (31%) | catalogued as COSV54502681; called by muse, mutect2, varscan2
- DNAH3 | c.1678G>A p.A560T | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as rs201150477, COSV54502714; called by muse, mutect2, varscan2
- DNAH9 | c.6727G>A p.D2243N | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs188273752, COSV52333477, COSV52338232; called by muse, mutect2, varscan2
- DOCK6 | c.2637G>C p.K879N | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV53910914; called by muse, mutect2, varscan2
- DOT1L | c.1251G>A p.M417I | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.079); catalogued as COSV67107875; called by muse, varscan2
- DOT1L | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV67107890; called by muse, mutect2, varscan2
- DSP | c.4687C>G p.L1563V | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV65791001; called by muse, mutect2, varscan2
- EAF1 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 40/309 reads (13%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.992); catalogued as COSV67657186; called by muse, varscan2
- EIF2B5 | c.1571-2A>C p.X524_splice (on ENST00000647909; = p.X516_splice on NM_003907.3) | Splice Site (SNP) | VAF 6/19 reads (32%) | catalogued as rs777899688; called by muse, mutect2, varscan2
- EIF4G2 | c.2565C>G p.F855L | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.122); catalogued as COSV60596096; called by muse, varscan2
- EIF4G2 | c.2342C>T p.S781F | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs766825276, COSV60596102; called by muse, mutect2, varscan2
- EIF4G2 | c.2014C>A p.P672T | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60596114; called by muse, mutect2, varscan2
- EIF4G2 | c.774G>A p.M258I | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.159); catalogued as COSV60596124; called by muse, mutect2, varscan2
- ELAVL2 | c.282G>C p.E94D | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV56357220, COSV99807293; called by muse, mutect2, varscan2
- ELAVL4 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV63914142; called by muse, mutect2, varscan2
- ELF1 | c.1627C>T p.Q543* | Nonsense Mutation (SNP) | VAF 11/116 reads (9%) | catalogued as rs776686002; called by muse, mutect2
- EMILIN2 | c.2277G>C p.K759N | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV54420989, COSV54424811; called by muse, mutect2, varscan2
- EPB41L1 | c.1837A>G p.T613A | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); catalogued as rs1308937521, COSV52433471; called by muse, mutect2, varscan2
- ERGIC2 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV64111327; called by muse, mutect2, varscan2
- ERLEC1 | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51750568; called by muse, mutect2, varscan2
- ERO1B | c.738C>G p.F246L | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV51595220; called by muse, mutect2, varscan2
- EXOC6B | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV55544764; called by muse, mutect2, varscan2
- EXT1 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1397695425, COSV65474853; called by muse, mutect2, varscan2
- FADS1 | c.546G>A p.M182I | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as COSV57244805; called by muse, mutect2, varscan2
- FAM83E | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated (0.4); PolyPhen benign (0.033); catalogued as rs1568420921, COSV54367936, COSV99613688; called by muse, mutect2, varscan2
- FANCA | c.976C>T p.Q326* | Nonsense Mutation (SNP) | VAF 10/62 reads (16%) | catalogued as rs758641682; called by muse, mutect2, varscan2
- FAT1 | c.9385C>G p.P3129A | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.427); catalogued as COSV71673549; called by muse, mutect2
- FBXL19 | c.1019C>T p.S340L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.066); catalogued as rs747798201, COSV57940651; called by muse, mutect2, varscan2
- FBXO48 | c.464G>C p.R155T | Missense Mutation (SNP) | VAF 41/243 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58142394, COSV58147515; called by muse, mutect2, varscan2
- FGA | c.744G>C p.W248C | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV57392723; called by muse, mutect2, varscan2
- FHOD1 | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV50758587; called by muse, mutect2, varscan2
- FN3K | c.652C>G p.L218V | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56181303; called by muse, mutect2, varscan2
- FOLH1 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.65); catalogued as COSV57052348, COSV57056022; called by muse, mutect2
- FOXN2 | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61316909; called by muse, mutect2, varscan2
- FOXP2 | c.1852G>T p.E618* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as COSV63483930, COSV63486114; called by muse, mutect2, varscan2
- FRMD1 | c.725C>G p.P242R | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV51959910, COSV51960389; called by muse, mutect2, varscan2
- FRS2 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1249741622, COSV54723141; called by muse, mutect2, varscan2
- FRS3 | c.830C>G p.S277C | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.527); catalogued as COSV52483930; called by muse, mutect2
- FSIP2 | c.16963G>A p.E5655K | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV58087129; called by muse, mutect2
- GALR2 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV57161507; called by muse, mutect2, varscan2
- GARNL3 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as rs1398652956, COSV59226138; called by muse, mutect2
- GBF1 | c.1043C>T p.S348L (on ENST00000369983 / NM_001377137.1; = p.S347L on NM_004193.3) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as COSV64142692; called by muse, mutect2, varscan2
- GFM1 | c.1426G>C p.E476Q | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51831039; called by muse, mutect2, varscan2
- GJD2 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.214); catalogued as COSV51746984; called by muse, mutect2, varscan2
- GLYCTK | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.107); catalogued as rs746478621, COSV59793018; called by muse, mutect2, varscan2
- GOLGB1 | c.6890G>A p.R2297H | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as rs772445249, COSV61461586; called by muse, mutect2, varscan2
- GPR180 | c.737-2del p.X246_splice | Splice Site (DEL) | VAF 38/100 reads (38%) | catalogued as COSV65385177; called by mutect2, pindel, varscan2
- GRB7 | c.1070C>G p.S357C | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); catalogued as COSV58446199; called by muse, mutect2, varscan2
- GRHPR | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV58941225; called by muse, mutect2, varscan2
- GSTA4 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV63955114; called by muse, mutect2, varscan2
- GTF2H3 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.653); catalogued as COSV57458105; called by muse, mutect2, varscan2
- GZF1 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.27); catalogued as rs767325112, COSV57634708; called by muse, mutect2, varscan2
- H4C9 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as COSV62889599; called by muse, mutect2
- HAS3 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54705865; called by muse, mutect2, varscan2
- HEATR5B | c.2210C>T p.S737L | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV51848733; called by muse, mutect2
- HEBP1 | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs781347916, COSV50009290; called by muse, mutect2, varscan2
- HEPHL1 | c.3106G>A p.E1036K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.585); catalogued as COSV59889380; called by muse, mutect2, varscan2
- HFE | c.643C>T p.H215Y | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs778399184, COSV58512414; called by muse, mutect2, varscan2
- HJURP | c.1888G>A p.D630N | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV64978464; called by muse, mutect2, varscan2
- HLA-F | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.003); catalogued as COSV52574505; called by muse, mutect2, varscan2
- HNF4A | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV57379454; called by muse, mutect2, varscan2
- HRG | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV51643949; called by muse, mutect2, varscan2
- HRNR | c.1535G>A p.G512D | Missense Mutation (SNP) | VAF 133/395 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV64253976; called by muse, mutect2, varscan2
- HSD17B8 | c.281C>G p.S94C | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV63002250; called by muse, mutect2, varscan2
- HSD17B8 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.143); catalogued as COSV63002254; called by muse, mutect2, varscan2
- IL1RAPL1 | c.869T>C p.I290T | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.936); catalogued as COSV56237322; called by muse, mutect2, varscan2
- ILDR1 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56547573; called by muse, mutect2, varscan2
- INTS12 | c.337G>C p.D113H | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV60861562; called by muse, mutect2, varscan2
- IPO7 | c.1508G>A p.R503K | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63352512; called by muse, mutect2, varscan2
- IWS1 | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54866449; called by muse, mutect2, varscan2
- KAT2A | c.2495G>C p.G832A | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52424477; called by mutect2, varscan2
- KCNJ16 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV52250581; called by muse, mutect2
- KCNK4 | c.1052C>G p.S351W | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60453521; called by muse, mutect2, varscan2
- KHDC4 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.443); catalogued as COSV64164512; called by muse, mutect2, varscan2
- KIF18A | c.2556A>T p.K852N | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54180929, COSV99589165; called by muse, mutect2, varscan2
- KLHL34 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs767416363; called by muse, mutect2, varscan2
- KMT2C | c.2915G>A p.G972E | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51285736; called by muse, mutect2
- KRTAP19-4 | c.101G>A p.R34K | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.014); catalogued as COSV61858130, COSV61859138; called by muse, mutect2, varscan2
- LCTL | c.510G>C p.Q170H | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.205); catalogued as COSV58421490; called by muse, mutect2, varscan2
- LETMD1 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50396571; called by muse, mutect2, varscan2
- LIFR | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV54684305; called by mutect2, varscan2
- LRCH3 | c.1813C>G p.Q605E | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV58388640; called by muse, mutect2, varscan2
- LRFN5 | c.97C>G p.L33V | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV53242595; called by muse, mutect2, varscan2
- LRRC3 | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.039); catalogued as rs780581862, COSV52398613; called by muse, mutect2, varscan2
- LRRN4 | c.1413C>G p.I471M | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.359); catalogued as COSV66644345; called by muse, mutect2, varscan2
- MACF1 | c.12784C>T p.Q4262* (on ENST00000372915; = p.Q2195* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 331/383 reads (86%) | catalogued as COSV57109576; called by muse, mutect2, varscan2
- MAJIN | c.535T>G p.S179A | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.007); catalogued as COSV54164003; called by muse, mutect2, varscan2
- MAP1A | c.3606G>C p.E1202D | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.636); catalogued as COSV55805915; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3519G>C p.E1173D | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as rs754852466, COSV51598877; called by muse, mutect2, varscan2
- MBTD1 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 39/246 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1181991312, COSV64502757; called by muse, mutect2, varscan2
- MED13L | c.5125G>A p.E1709K | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV56115668; called by muse, mutect2, varscan2
- MED25 | c.989C>G p.P330R | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV57202920, COSV57207772; called by muse, mutect2, varscan2
- MEF2D | c.850C>T p.H284Y | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.579); catalogued as rs1355776353, COSV61726701; called by muse, mutect2, varscan2
- MEIS2 | c.157G>A p.A53T (on ENST00000561208 / NM_170675.5; = p.A40T on NM_002399.3) | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV54931297; called by muse, mutect2, varscan2
- MET | c.2709G>C p.L903F | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.486); catalogued as COSV59256664; called by muse, mutect2, varscan2
- MFRP | c.491C>G p.S164C (on ENST00000449574; = p.S540C on NM_031433.4) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV60989672; called by muse, mutect2, varscan2
- MGAT5B | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs553528918, COSV56924835; called by muse, mutect2, varscan2
- MIDEAS | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs1403351793, COSV54092511; called by muse, mutect2, varscan2
- MIDEAS | c.1166C>G p.S389C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV54092527; called by muse, mutect2, varscan2
- MIER3 | c.1381T>A p.Y461N (on ENST00000381199 / NM_001297599.2; = p.Y460N on NM_152622.4) | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV67082480; called by muse, mutect2, varscan2
- MIGA1 | c.169C>G p.L57V | Missense Mutation (SNP) | VAF 24/420 reads (6%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV100889763, COSV66222726; called by muse, mutect2
- MIOS | c.1847G>C p.R616T | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60766882; called by muse, mutect2, varscan2
- MMP14 | c.754G>T p.D252Y | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61287410; called by muse, mutect2, varscan2
- MMP8 | c.1261G>C p.E421Q | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.361); catalogued as COSV52630844; called by muse, mutect2, varscan2
- MOCOS | c.757C>T p.H253Y | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.95); PolyPhen benign (0.006); catalogued as rs748011762, COSV54340839; called by muse, mutect2, varscan2
- MRC1 | c.3631C>T p.L1211F | Missense Mutation (SNP) | VAF 39/255 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs976641411; called by muse, mutect2, varscan2
- MRPL3 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV53913302; called by muse, mutect2, varscan2
- MSH2 | c.1627G>A p.D543N | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as CD045345, COSV51875604, COSV51883048; called by muse, mutect2, varscan2
- MSH3 | c.1459C>G p.Q487E | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.061); catalogued as COSV54144313, COSV54163170; called by muse, mutect2, varscan2
- MSX1 | c.717G>C p.K239N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV66946928; called by muse, mutect2, varscan2
- MTMR11 | c.721G>C p.D241H (on ENST00000439741 / NM_001145862.2; = p.D169H on NM_181873.3) | Missense Mutation (SNP) | VAF 61/265 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63804715; called by muse, mutect2, varscan2
- MUC16 | c.11588G>C p.R3863T | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs778341926, COSV67443798, COSV67481122; called by muse, mutect2, varscan2
- MYH15 | c.1171G>C p.E391Q | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56304185, COSV99844178; called by muse, mutect2, varscan2
- MYH8 | c.2124T>G p.C708W | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV67959559, COSV67961665; called by muse, mutect2, varscan2
- MYH9 | c.4039G>A p.E1347K | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs765101192, COSV53381848; called by muse, mutect2, varscan2
- MYO9B | c.4393C>T p.R1465C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs537346242, COSV68276896; called by muse, mutect2
- N4BP1 | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.086); catalogued as COSV52209416; called by muse, mutect2, varscan2
- NAA25 | c.2622G>T p.K874N | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV55701869; called by muse, mutect2, varscan2
- NAGPA | c.1274G>C p.R425T | Missense Mutation (SNP) | VAF 6/58 reads (10%) | PolyPhen benign (0.001); catalogued as COSV56569168; called by muse, mutect2, varscan2
- NCKAP5 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV58426536; called by muse, mutect2, varscan2
- NEB | c.8704C>G p.L2902V | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV50808339; called by muse, mutect2, varscan2
- NISCH | c.3354G>C p.E1118D | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV61898328; called by muse, mutect2, varscan2
- NLRP10 | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.808); catalogued as COSV60778612; called by muse, mutect2, varscan2
- NLRP7 | c.2743A>T p.I915L (on ENST00000340844 / NM_206828.3; = p.I887L on NM_139176.3) | Missense Mutation (SNP) | VAF 16/199 reads (8%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.523); catalogued as COSV60170849; called by muse, mutect2
- NOS2 | c.1332G>T p.M444I | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.217); catalogued as COSV58221601; called by muse, mutect2, varscan2
- NPFF | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV57198948; called by muse, mutect2, varscan2
- NT5E | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs373328681, CM110836, COSV57627206; called by muse, mutect2, varscan2
- NUMA1 | c.5900G>A p.R1967Q | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs754124730, COSV52619685; called by muse, mutect2, varscan2
- NUP155 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV51526612; called by muse, mutect2, varscan2
- NUP214 | c.180G>T p.Q60H | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV55988967; called by muse, varscan2
- NXF1 | c.648G>C p.M216I | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.269); catalogued as COSV53672103; called by muse, mutect2, varscan2
- OR1S2 | c.959G>C p.R320T | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs368857095; called by muse, mutect2
- OR51D1 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.284); catalogued as COSV62913853; called by muse, mutect2, varscan2
- OR8D1 | c.831C>G p.F277L | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV63441637, COSV63441689; called by muse, mutect2, varscan2
- ORC3 | c.1483G>C p.E495Q | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV57638330; called by muse, mutect2
- OTUD6A | c.512G>C p.R171P | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57974035; called by muse, mutect2
- OTUD7B | c.2213G>A p.R738Q | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.357); catalogued as rs782204024, COSV64915022; called by muse, mutect2, varscan2
- PCDH10 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 40/256 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1332372413, COSV52087391; called by muse, mutect2, varscan2
- PCDHB4 | c.2020G>A p.E674K | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV52019458; called by muse, mutect2, varscan2
- PDZRN3 | c.1400G>A p.G467E | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55190943; called by muse, mutect2, varscan2
- PHF20 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.068); catalogued as COSV59184424, COSV59187980; called by muse, mutect2, varscan2
- PIKFYVE | c.5977C>T p.H1993Y | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV52236835; called by muse, mutect2, varscan2
- PLCH1 | c.1435-1G>C p.X479_splice (on ENST00000340059 / NM_001130960.2; = p.X491_splice on NM_014996.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 5/51 reads (10%) | catalogued as COSV100398542, COSV58186005; called by muse, mutect2, varscan2
- PLP2 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.84); catalogued as rs368640397, COSV66239307; called by muse, mutect2, varscan2
- PLXNC1 | c.4032C>G p.F1344L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.426); catalogued as COSV51569197, COSV51572923; called by muse, mutect2, varscan2
- PNPO | c.439G>A p.E147K (on ENST00000225573; = p.E190K on NM_018129.4) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.395); catalogued as COSV56666148; called by muse, mutect2, varscan2
- POLA1 | c.4108C>G p.L1370V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.68); PolyPhen benign (0.068); catalogued as COSV66883592; called by muse, mutect2, varscan2
- POLQ | c.4904C>G p.S1635* | Nonsense Mutation (SNP) | VAF 68/246 reads (28%) | catalogued as COSV99951678; called by muse, mutect2, varscan2
- POLR2F | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV50777640; called by muse, mutect2, varscan2
- PPP3CB | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.104); catalogued as COSV61150888; called by muse, mutect2, varscan2
- PRKD2 | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.308); catalogued as COSV52184474; called by muse, mutect2, varscan2
- PROCA1 | c.1066C>A p.P356T (on ENST00000439862 / NM_001366301.1; = p.P328T on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs774832594, COSV56385237; called by muse, mutect2, varscan2
- PRR13 | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.996); catalogued as COSV65768896; called by muse, varscan2
- PSKH2 | c.777C>G p.F259L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as COSV52609095; called by muse, mutect2, varscan2
- PSMC3 | c.180G>C p.L60F | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.071); catalogued as COSV54080163; called by muse, varscan2
- PSME1 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.247); catalogued as rs144591736, COSV52823279; called by muse, mutect2, varscan2
- PTGER4 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV56720005; called by muse, mutect2, varscan2
- PTPRJ | c.232C>G p.Q78E | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV69249727; called by muse, mutect2, varscan2
- QKI | c.317G>C p.R106T | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV51689237; called by muse, mutect2, varscan2
- RAB29 | c.178C>G p.Q60E | Missense Mutation (SNP) | VAF 114/233 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV52520697, COSV99353133; called by muse, mutect2, varscan2
- RAD1 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as COSV57714834; called by muse, mutect2, varscan2
- RAD51D | c.957G>C p.Q319H | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV60003854; called by muse, mutect2, varscan2
- RANGAP1 | c.1412C>A p.S471Y | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as COSV62362391; called by muse, mutect2, varscan2
- RBFA | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV51532793; called by muse, mutect2, varscan2
- RBM4B | c.1026G>A p.M342I | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV59496418; called by muse, mutect2, varscan2
- RECQL5 | c.2701G>C p.D901H | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.081); catalogued as COSV58637241; called by muse, mutect2, varscan2
- RECQL5 | c.2495G>A p.C832Y | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58637260; called by muse, mutect2, varscan2
- RECQL5 | c.2374G>A p.E792K | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.131); catalogued as COSV58637276; called by muse, mutect2, varscan2
- RFLNB | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61239042; called by muse, mutect2, varscan2
- RIC8B | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.427); catalogued as rs745611692, COSV62693223; called by muse, mutect2, varscan2
- RINL | c.583G>A p.A195T (on ENST00000591812 / NM_001195833.2; = p.A81T on NM_198445.4) | Missense Mutation (SNP) | VAF 69/171 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV61573846; called by muse, mutect2, varscan2
- RNF113B | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as rs199939990, COSV57434212; called by muse, mutect2, varscan2
- RNF8 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV57720562; called by muse, mutect2, varscan2
- RPL4 | c.654C>G p.I218M | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as COSV57178168; called by muse, mutect2, varscan2
- RPS6 | c.690G>C p.K230N | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV59547492; called by muse, varscan2
- RPS6KA5 | c.846G>C p.M282I | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV56219325; called by muse, mutect2
- RTCB | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as COSV53277245; called by muse, mutect2, varscan2
- RTN3 | c.1564G>A p.E522K (on ENST00000377819 / NM_001265589.2; = p.E503K on NM_201428.3) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV58026954; called by muse, mutect2
- RUVBL2 | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55484172; called by muse, mutect2, varscan2
- RYR1 | c.5074C>G p.Q1692E | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62088524; called by muse, mutect2, varscan2
- SCN3A | c.5391G>A p.W1797* | Nonsense Mutation (SNP) | VAF 8/85 reads (9%) | catalogued as COSV51818008; called by muse, mutect2, varscan2
- SEL1L3 | c.2143G>C p.E715Q | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV53536086; called by muse, mutect2, varscan2
- SERPINA12 | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as COSV57942171; called by muse, mutect2, varscan2
- SH2D3C | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs771383125, COSV59118238; called by muse, mutect2, varscan2
- SKIL | c.1800G>C p.Q600H | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52058205; called by muse, mutect2, varscan2
- SLC4A11 | c.1884C>A p.F628L | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV66260270; called by muse, mutect2, varscan2
- SLC66A1 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.148); catalogued as rs773086016, COSV64320501; called by muse, mutect2, varscan2
- SLC6A13 | c.1468C>T p.P490S | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.242); catalogued as rs1439018595, COSV58255204; called by muse, mutect2, varscan2
- SLCO1B3 | c.919C>G p.Q307E | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV53931962, COSV99682418; called by muse, mutect2, varscan2
- SMAP1 | c.836C>T p.S279F (on ENST00000370455 / NM_001044305.3; = p.S252F on NM_021940.5) | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as COSV57635159; called by muse, mutect2
- SMOC2 | c.931G>A p.E311K (on ENST00000356284 / NM_001166412.2; = p.E322K on NM_022138.3) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); catalogued as COSV62433732; called by muse, mutect2, varscan2
- SP100 | c.2623C>G p.Q875E | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV60841391; called by muse, mutect2, varscan2
- SPICE1 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated (0.99); PolyPhen benign (0.442); catalogued as COSV55617972; called by muse, mutect2, varscan2
- SPINK5 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56248376, COSV99805944; called by muse, mutect2
- SRCAP | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.071); catalogued as rs1452956904, COSV52667381; called by muse, mutect2, varscan2
- SULF2 | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs1018156103, COSV63413819; called by muse, mutect2, varscan2
- SYBU | c.1222G>C p.D408H (on ENST00000276646 / NM_001099754.2; = p.D407H on NM_017786.6) | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.439); catalogued as COSV52614122; called by muse, mutect2, varscan2
- SYMPK | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV55609523; called by muse, mutect2, varscan2
- SYNE2 | c.8675C>T p.S2892L | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100647082, COSV59939302; called by muse, mutect2, varscan2
- SYNJ1 | c.2067C>G p.I689M | Missense Mutation (SNP) | VAF 39/268 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV59143773; called by muse, varscan2
- SYTL2 | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); catalogued as COSV60355683, COSV60364905; called by muse, mutect2, varscan2
- TAF6 | c.1272G>C p.Q424H | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV100612837, COSV59840541; called by muse, varscan2
- TAS1R3 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs765980224, COSV59562128; called by mutect2, varscan2
- TBC1D4 | c.3176C>G p.S1059C | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66487566; called by muse, mutect2, varscan2
- TBC1D8B | c.1603G>C p.D535H | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52175591; called by muse, mutect2, varscan2
- TCP11L2 | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.16); catalogued as COSV54428878; called by muse, mutect2, varscan2
- TENT5A | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as COSV60787284; called by muse, mutect2, varscan2
- TIMP3 | c.441C>T p.I147= | Splice Region (SNP) | VAF 12/52 reads (23%) | catalogued as COSV56667079; called by muse, mutect2
- TLR10 | c.709C>G p.L237V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.045); catalogued as COSV58299052; called by muse, mutect2
- TLR5 | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs750103973, COSV60557856; called by mutect2, varscan2
- TMED7 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.781); catalogued as rs750995690, COSV56694581; called by muse, mutect2, varscan2
- TMEM145 | c.540C>G p.I180M | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.328); catalogued as COSV56623776; called by muse, mutect2, varscan2
- TMEM41B | c.581G>C p.R194T | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV55154335; called by muse, varscan2
- TMPRSS7 | c.1096G>A p.E366K (on ENST00000452346; = p.E240K on NM_001042575.2) | Missense Mutation (SNP) | VAF 35/275 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.061); catalogued as COSV69979530; called by muse, mutect2, varscan2
- TOPORS | c.1502C>T p.S501F | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as COSV62116092, COSV62117516; called by muse, mutect2, varscan2
- TOPORS | c.331G>C p.D111H | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV62116098; called by muse, mutect2, varscan2
- TP53 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as rs587781845, COSV52671445, COSV52701260, COSV52703282; ClinVar: uncertain significance; called by muse, varscan2
- TRAPPC11 | c.2338G>A p.E780K | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58214447; called by muse, mutect2, varscan2
- TRIM28 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 26/204 reads (13%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.587); catalogued as COSV53398802; called by muse, mutect2, varscan2
- TRPC4 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58990158; called by muse, mutect2, varscan2
- TTC21B | c.3241G>C p.E1081Q | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.848); catalogued as COSV54627669; called by muse, mutect2, varscan2
- TTC39A | c.198G>C p.E66D | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.281); catalogued as COSV52956576; called by muse, mutect2, varscan2
- TTN | c.94564G>A p.E31522K (on ENST00000591111; = p.E24098K on NM_003319.4) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | PolyPhen benign (0.062); catalogued as COSV59880667; called by muse, mutect2, varscan2
- TTN | c.43240C>T p.R14414C (on ENST00000591111; = p.R6990C on NM_003319.4) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | PolyPhen benign (0.001); catalogued as rs1012450335, COSV59880703; called by muse, mutect2, varscan2
- TUBB2A | c.699G>A p.M233I | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.009); catalogued as COSV100373796; called by muse, mutect2, varscan2
- TXNDC11 | c.1165G>A p.E389K (on ENST00000356957 / NM_001303447.2; = p.E362K on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.207); catalogued as rs143169078; called by muse, mutect2, varscan2
- TXNRD1 | c.1609G>A p.E537K (on ENST00000525566 / NM_001093771.3; = p.E439K on NM_003330.4) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61597226, COSV61600272; called by muse, mutect2, varscan2
- TYK2 | c.403G>C p.D135H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.519); catalogued as COSV53384639; called by muse, mutect2, varscan2
- U2AF2 | c.1057C>G p.Q353E | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV58272334; called by muse, mutect2, varscan2
- UGGT1 | c.2611G>A p.D871N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV52132247; called by mutect2, varscan2
- UGT1A5 | c.707C>G p.S236C | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59381478; called by muse, mutect2, varscan2
- USH2A | c.5885G>A p.R1962K | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs1488598823, COSV56326245; called by muse, mutect2, varscan2
- USP25 | c.2436C>G p.I812M | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs769399229, COSV53480652, COSV53481446; called by muse, mutect2, varscan2
- UTP20 | c.7078G>A p.E2360K | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as rs769744992, COSV55371885; called by muse, mutect2, varscan2
- UVSSA | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as rs971017241; called by muse, mutect2, varscan2
- VANGL1 | c.682G>C p.D228H | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59619265, COSV59621574; called by muse, mutect2, varscan2
- VCAN | c.4007G>A p.R1336Q | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.207); catalogued as rs372244245, COSV54098984; called by muse, mutect2, varscan2
- VIT | c.685T>C p.W229R | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV64895116; called by muse, mutect2
- VWA5A | c.1903G>C p.D635H | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV64411773; called by muse, mutect2, varscan2
- WASF2 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1557598015; called by muse, mutect2, varscan2
- WDFY3 | c.6202C>G p.L2068V | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55693140; called by muse, mutect2, varscan2
- WDR49 | c.1492G>A p.D498N (on ENST00000308378 / NM_001366158.1; = p.D839N on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); catalogued as COSV57701923; called by muse, mutect2, varscan2
- XXYLT1 | c.1135G>A p.V379I | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as rs570090519, COSV59980883; called by muse, mutect2, varscan2
- ZC3H13 | c.1636G>C p.E546Q | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.042); catalogued as COSV54447460; called by muse, mutect2
- ZDHHC6 | c.100T>A p.C34S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.198); catalogued as COSV65563813; called by muse, mutect2, varscan2
- ZFPM2 | c.1883C>G p.S628C | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV101022972, COSV65872521; called by muse, mutect2, varscan2
- ZIC1 | c.1232C>T p.S411F | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1162132611, COSV51550528, COSV51558832; called by muse, mutect2, varscan2
- ZMYND19 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.453); catalogued as COSV53021277; called by muse, mutect2, varscan2
- ZNF536 | c.2702G>A p.G901E | Missense Mutation (SNP) | VAF 34/257 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV62818080; called by muse, mutect2, varscan2
- ZNF544 | c.1016C>T p.S339L | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV54134109; called by muse, mutect2, varscan2
- ZNF671 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.484); catalogued as COSV58051634; called by muse, mutect2
- ZNF681 | c.1876G>A p.D626N | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV68073376; called by muse, mutect2
- ZNF681 | c.1491G>C p.K497N | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.868); catalogued as COSV68073378, COSV68075645; called by muse, mutect2, varscan2
- ZNF681 | c.374G>C p.G125A | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.038); catalogued as COSV68073381, COSV68075974; called by muse, mutect2, varscan2
- ZNF695 | c.1365G>C p.K455N | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV60584629; called by muse, mutect2, varscan2
- ZNF808 | c.1088G>C p.R363T | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.77); catalogued as COSV63118595, COSV63119345; called by muse, mutect2
- ZNF831 | c.3611C>T p.S1204F | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64037200; called by muse, mutect2, varscan2
- ZRANB1 | c.195G>C p.L65F | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV62841466; called by muse, mutect2, varscan2
- AC245033.1 | c.1463C>G p.A488G | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- ANKLE2 | c.645G>C p.R215S | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.1); called by muse, mutect2
- ARHGAP24 | c.646C>T p.R216* (on ENST00000395184 / NM_001025616.3; = p.R123* on NM_031305.3) | Nonsense Mutation (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- ARHGAP35 | c.16_23del p.K6Cfs*40 | Frame Shift Del (DEL) | VAF 16/170 reads (9%) | called by mutect2, pindel
- BAX | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 61/126 reads (48%) | called by muse, mutect2, varscan2
- CKAP2 | c.1299G>C p.L433F (on ENST00000378037 / NM_001098525.2; = p.L432F on NM_018204.5) | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CLK1 | c.839A>T p.H280L | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CPB2 | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 26/99 reads (26%) | called by muse, mutect2, varscan2
- DPYSL4 | c.856G>C p.D286H | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.135); called by mutect2, varscan2
- FCGR3B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GFM1 | c.1579G>T p.E527* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- IGBP1P2 | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ITGAV | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.028); called by muse, mutect2
- KMT2A | c.7342_7354del p.E2448* | Frame Shift Del (DEL) | VAF 27/77 reads (35%) | called by mutect2, pindel, varscan2
- LRP10 | c.2119G>A p.E707K | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- MEP1A | c.1372C>T p.R458* | Nonsense Mutation (SNP) | VAF 24/73 reads (33%) | called by muse, mutect2, varscan2
- MIDEAS | c.1753G>C p.E585Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.063); called by muse, mutect2
- MRC1 | c.4058A>G p.Y1353C | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- OR10H1 | c.687C>G p.I229M | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- PRDM5 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 36/236 reads (15%) | called by muse, mutect2, varscan2
- RFTN2 | c.591G>A p.W197* | Nonsense Mutation (SNP) | VAF 17/170 reads (10%) | called by muse, mutect2, varscan2
- ROCK2 | c.213C>G p.F71L | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2
- SEC16A | c.700G>T p.E234* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- SMG9 | c.1562G>C p.*521Sext*38 | Nonstop Mutation (SNP) | VAF 13/92 reads (14%) | called by muse, varscan2
- SPTLC1 | c.1013C>A p.S338* | Nonsense Mutation (SNP) | VAF 10/61 reads (16%) | called by muse, mutect2, varscan2
- SUPT16H | c.2152_2154del p.I718del | In Frame Del (DEL) | VAF 14/99 reads (14%) | called by pindel, varscan2
- SVIL | c.2018C>G p.S673* (on ENST00000355867 / NM_021738.3; = p.S279* on NM_003174.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/71 reads (17%) | called by muse, mutect2, varscan2
- TP53INP2 | c.88G>C p.D30H | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2
- TRIM37 | c.2671G>T p.G891* | Nonsense Mutation (SNP) | VAF 16/100 reads (16%) | called by muse, mutect2, varscan2
- TRIO | c.5977G>A p.E1993K | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); called by muse, varscan2
- TRMT10A | c.251C>G p.S84* | Nonsense Mutation (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2, varscan2
- TSC22D1 | c.2444C>G p.S815* | Nonsense Mutation (SNP) | VAF 18/124 reads (15%) | called by muse, mutect2, varscan2
- UBAP2L | c.1311G>C p.E437D | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, varscan2
- UBE2Z | c.1022C>T p.S341L | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- UBR7 | c.1278G>C p.*426Yext*4 | Nonstop Mutation (SNP) | VAF 10/47 reads (21%) | called by muse, varscan2
- ZFP37 | c.1169C>G p.S390* | Nonsense Mutation (SNP) | VAF 16/105 reads (15%) | called by muse, mutect2, varscan2
- ABCC3 | c.1566C>G p.L522= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV53317043; called by muse, mutect2
- AC097637.1 | c.189G>A p.Q63= | Silent (SNP) | VAF 2/23 reads (9%) | called by muse, mutect2
- AJAP1 | c.216G>A p.A72= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs745464898, COSV100981973; called by muse, mutect2, varscan2
- ANKMY1 | c.375C>A p.I125= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV56029940, COSV99802194; called by muse, mutect2, varscan2
- ARID1A | c.2208C>T p.I736= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV61371599, COSV61374896; called by muse, mutect2, varscan2
- ASH1L | c.7524G>A p.V2508= (on ENST00000368346 / NM_001366177.2; = p.V2503= on NM_018489.3) | Silent (SNP) | VAF 25/90 reads (28%) | catalogued as COSV64205334; called by muse, mutect2, varscan2
- ATAD2B | c.2736C>G p.L912= | Silent (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- ATP6V1A | c.1827G>A p.Q609= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV56360893, COSV56363660; called by muse, mutect2, varscan2
- BAX | c.432C>T p.L144= | Silent (SNP) | VAF 47/98 reads (48%) | catalogued as COSV53168963; called by muse, mutect2, varscan2
- BHLHE41 | c.201G>A p.L67= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV54378199; called by muse, mutect2, varscan2
- BMPR2 | c.2169C>T p.F723= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV65807491; called by muse, mutect2, varscan2
- BMX | c.930C>G p.L310= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV59590113; called by muse, mutect2, varscan2
- CABIN1 | c.2526C>T p.V842= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV54077421; called by muse, mutect2
- CEMIP2 | c.3183C>G p.V1061= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as COSV65484264, COSV65485104; called by muse, mutect2, varscan2
- CHMP7 | c.558C>T p.L186= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs759170647, COSV57532165; called by muse, mutect2, varscan2
- CXCL13 | c.30C>T p.L10= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV54488922; called by muse, mutect2, varscan2
- DENND4B | c.3021G>C p.L1007= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs1395334700; called by muse, mutect2, varscan2
- DIAPH3 | c.3270G>A p.Q1090= (on ENST00000400324 / NM_001042517.2; = p.Q827= on NM_030932.3) | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as rs369779991; called by muse, mutect2, varscan2
- DNAH3 | c.3054G>A p.V1018= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV54502696; called by muse, mutect2, varscan2
- DOP1B | c.1332C>G p.L444= | Silent (SNP) | VAF 18/118 reads (15%) | catalogued as rs1235215306, COSV67692004; called by muse, mutect2, varscan2
- DOT1L | c.1617G>A p.Q539= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV67107880; called by muse, mutect2, varscan2
- DOT1L | c.1668G>A p.V556= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as rs1195563771, COSV67107886; called by muse, varscan2
- DOT1L | c.2343G>A p.L781= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as rs1177486690, COSV67107895, COSV67110833; called by muse, mutect2, varscan2
- EGF | c.1162C>T p.L388= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV54475510; called by muse, mutect2, varscan2
- EIF2AK3 | c.2052C>T p.L684= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as rs1013032001, COSV57544839; called by muse, mutect2
- EIF4G3 | c.160C>T p.L54= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV51673785; called by muse, mutect2, varscan2
- EPPK1 | c.3939G>C p.L1313= | Silent (SNP) | VAF 24/107 reads (22%) | catalogued as rs781938095, COSV73260786; called by muse, mutect2, varscan2
- FAM50B | c.714C>T p.I238= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV66654457; called by muse, mutect2, varscan2
- FBXO27 | c.462C>T p.F154= | Silent (SNP) | VAF 20/177 reads (11%) | catalogued as rs1486464560, COSV53071965; called by muse, mutect2, varscan2
- FMNL1 | c.3231C>T p.F1077= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV58955036; called by muse, mutect2, varscan2
- FOXL1 | c.84C>G p.L28= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV57213644; called by muse, mutect2, varscan2
- GGT7 | c.1545C>T p.F515= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV60539617; called by muse, mutect2, varscan2
- GRHL1 | c.1251C>T p.I417= | Silent (SNP) | VAF 45/294 reads (15%) | catalogued as rs752155021, COSV61406305; called by muse, mutect2, varscan2
- H2BC9 | c.264G>C p.S88= | Silent (SNP) | VAF 6/123 reads (5%) | catalogued as rs1489147078, COSV55099128; called by muse, mutect2
- HAAO | c.495C>G p.L165= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as rs1223259769, COSV54309682; called by muse, mutect2, varscan2
- HEATR5B | c.2340C>G p.V780= | Silent (SNP) | VAF 25/121 reads (21%) | catalogued as COSV51848720, COSV51852953; called by muse, mutect2, varscan2
- HEPHL1 | c.312G>A p.L104= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV59889375; called by muse, mutect2, varscan2
- HLA-E | c.30C>G p.L10= | Silent (SNP) | VAF 38/126 reads (30%) | catalogued as COSV64927207; called by muse, mutect2, varscan2
- HM13 | c.660C>A p.V220= | Silent (SNP) | VAF 26/209 reads (12%) | catalogued as COSV59435661; called by muse, mutect2, varscan2
- HOXC4 | c.300G>A p.P100= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100324285; called by muse, mutect2
- ICE1 | c.6516G>C p.L2172= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs775293297; called by muse, mutect2
- IGHD | c.591G>A p.L197= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV101162814; called by muse, mutect2
- IGHMBP2 | c.1983C>T p.H661= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as rs752907111, COSV54819994; called by muse, mutect2, varscan2
- ITGAV | c.1494C>G p.L498= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV53709122; called by muse, mutect2, varscan2
- KANSL3 | c.1179C>G p.L393= | Silent (SNP) | VAF 20/123 reads (16%) | catalogued as COSV62615665; called by muse, mutect2, varscan2
- KATNIP | c.255G>A p.R85= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as rs1202788674, COSV55173225; called by muse, mutect2, varscan2
- KCNJ16 | c.663C>G p.L221= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV52250562; called by muse, mutect2, varscan2
- KDELR1 | c.246C>T p.F82= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV58101486; called by muse, mutect2, varscan2
- KIAA0100 | c.5688G>T p.L1896= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV56380653; called by muse, mutect2, varscan2
- KIR2DL3 | c.783C>G p.L261= | Silent (SNP) | VAF 22/164 reads (13%) | catalogued as COSV60895321, COSV60898631; called by muse, varscan2
- KLHDC4 | c.915G>A p.P305= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs200674595, COSV54505982; called by muse, mutect2, varscan2
- KMT2B | c.4215G>C p.L1405= | Silent (SNP) | VAF 17/138 reads (12%) | catalogued as COSV55856569; called by muse, mutect2, varscan2
- L3MBTL1 | c.2082C>T p.L694= (on ENST00000418998 / NM_001377303.1; = p.L604= on NM_015478.7) | Silent (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- LAMA1 | c.2424C>G p.L808= | Silent (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2
- LBP | c.399C>G p.V133= | Silent (SNP) | VAF 15/145 reads (10%) | catalogued as COSV54138559; called by muse, mutect2, varscan2
- LLGL2 | c.228G>A p.V76= | Silent (SNP) | VAF 21/152 reads (14%) | catalogued as COSV51342057; called by muse, mutect2, varscan2
- LNPEP | c.2139C>T p.I713= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV51476102; called by muse, mutect2, varscan2
- LTBP1 | c.1389C>T p.T463= (on ENST00000404816 / NM_206943.4; = p.T137= on NM_000627.4) | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV63179528; called by muse, mutect2
- MAP3K5 | c.1668G>C p.V556= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as COSV62886921; called by muse, mutect2
- MET | c.4023C>T p.F1341= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as COSV59256671, COSV59265801; called by muse, mutect2, varscan2
- MROH1 | c.3156C>T p.I1052= | Silent (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- MSH3 | c.57G>A p.A19= | Silent (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- MST1R | c.2520G>A p.G840= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as COSV56564316; called by muse, mutect2, varscan2
- MTFR1 | c.732G>A p.E244= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV50951074; called by muse, mutect2
- MYC | c.153G>A p.K51= (on ENST00000377970; = p.K66= on NM_002467.6) | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as COSV52374284, COSV99422094; called by muse, mutect2
- MYH1 | c.5052G>A p.L1684= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs765747020, COSV56843466; called by muse, mutect2, varscan2
- NPHS1 | c.3426G>A p.L1142= | Silent (SNP) | VAF 16/193 reads (8%) | catalogued as COSV62286296; called by muse, mutect2
- NUP85 | c.201C>T p.I67= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as COSV55462723; called by muse, mutect2, varscan2
- NWD1 | c.672C>T p.L224= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV60337617, COSV60341216; called by muse, mutect2, varscan2
- OR10G9 | c.126C>A p.L42= | Silent (SNP) | VAF 28/122 reads (23%) | catalogued as COSV66685701; called by muse, mutect2, varscan2
- OR3A1 | c.504G>A p.T168= | Silent (SNP) | VAF 49/127 reads (39%) | catalogued as rs201559764, COSV60162478, COSV60163359; called by muse, mutect2, varscan2
- OR4E2 | c.306C>T p.F102= | Silent (SNP) | VAF 83/227 reads (37%) | catalogued as COSV57731337; called by muse, mutect2, varscan2
- OSBP2 | c.1080C>T p.F360= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV60239520; called by muse, mutect2, varscan2
- OTX2 | c.198C>T p.F66= (on ENST00000408990 / NM_172337.3; = p.F74= on NM_021728.4) | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV59765339; called by muse, mutect2, varscan2
- PAAF1 | c.918G>A p.L306= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV60155699; called by muse, mutect2
- PAQR8 | c.291C>T p.A97= | Silent (SNP) | VAF 14/103 reads (14%) | catalogued as rs1323191474, COSV62441967; called by muse, mutect2, varscan2
- PCBP3 | c.963G>A p.Q321= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV68406491; called by muse, mutect2, varscan2
- PCDHA1 | c.1362G>A p.A454= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as rs782735155, COSV65372597; called by muse, mutect2, varscan2
- PCDHB10 | c.1890G>A p.L630= | Silent (SNP) | VAF 11/87 reads (13%) | called by muse, mutect2, varscan2
- PCDHGA1 | c.1836C>T p.S612= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as rs770128704; called by muse, mutect2, varscan2
- PDCD10 | c.174C>T p.L58= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs1274956108, COSV101208521, COSV67101973; called by muse, mutect2, varscan2
- PER2 | c.354G>A p.L118= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as rs756475348, COSV54521278; called by muse, mutect2, varscan2
- PIGA | c.261C>G p.L87= | Silent (SNP) | VAF 46/91 reads (51%) | catalogued as COSV61236811; called by muse, mutect2, varscan2
- PIK3CG | c.1779T>C p.F593= | Silent (SNP) | VAF 31/103 reads (30%) | catalogued as rs764655221, COSV63245383; called by muse, mutect2, varscan2
- PKHD1L1 | c.7657C>T p.L2553= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV65736828; called by muse, mutect2, varscan2
- PLEKHA7 | c.2821C>T p.L941= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs750462071, COSV60580237; called by muse, mutect2, varscan2
- PLP2 | c.399C>T p.F133= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV66239305; called by muse, mutect2, varscan2
- PPP1R12C | c.336G>A p.E112= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as COSV54735894; called by muse, mutect2
- PPP2R1A | c.1509C>T p.F503= | Silent (SNP) | VAF 63/140 reads (45%) | catalogued as rs1241423356, COSV59042338; called by muse, mutect2, varscan2
- PRAMEF20 | c.1427G>A p.*476= | Silent (SNP) | VAF 8/205 reads (4%) | called by muse, mutect2
- PRKCD | c.21C>T p.I7= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as rs373946656; called by muse, mutect2
- PRPF4B | c.1992C>G p.L664= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV61783270; called by muse, mutect2, varscan2
- PSMD3 | c.396C>T p.L132= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as rs746069887, COSV52856359; called by muse, mutect2, varscan2
- RAB6C | c.444G>A p.L148= | Silent (SNP) | VAF 37/219 reads (17%) | catalogued as COSV69339264; called by muse, mutect2, varscan2
- RFPL1 | c.276C>T p.P92= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as COSV62977356; called by muse, mutect2, varscan2
- RMND1 | c.1026G>A p.V342= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV60549916; called by muse, mutect2, varscan2
- SFTPD | c.483C>T p.L161= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as rs987052380, COSV64852599; called by muse, varscan2
- SLC12A7 | c.1720C>T p.L574= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV53754360; called by muse, mutect2, varscan2
- SLC32A1 | c.1437C>G p.R479= | Silent (SNP) | VAF 4/65 reads (6%) | catalogued as COSV54145611; called by muse, mutect2
- TAS2R42 | c.360C>T p.L120= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV62084333, COSV62084391; called by muse, mutect2, varscan2
- TAS2R8 | c.246G>A p.Q82= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as COSV53687762, COSV53689877; called by muse, mutect2, varscan2
- TCF25 | c.135C>T p.V45= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- TDRD1 | c.276C>T p.I92= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV52587313; called by muse, mutect2, varscan2
- TENM3 | c.3531G>A p.A1177= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs370690717; called by muse, mutect2, varscan2
- TF | c.1803C>T p.A601= | Silent (SNP) | VAF 14/221 reads (6%) | catalogued as COSV53917575; called by muse, mutect2
- THEM4 | c.330C>T p.L110= | Silent (SNP) | VAF 10/133 reads (8%) | catalogued as rs763627984, COSV64294900, COSV64295794; called by muse, mutect2
- THOC5 | c.1155G>A p.L385= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as rs150202892; called by muse, mutect2, varscan2
- TIAM1 | c.3423C>G p.L1141= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV54537078; called by muse, mutect2, varscan2
- TNXB | c.10560G>A p.V3520= (on ENST00000647633; = p.V3273= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV64473110; called by muse, mutect2, varscan2
- TRIB1 | c.954C>G p.L318= | Silent (SNP) | VAF 7/115 reads (6%) | catalogued as COSV61334204; called by muse, mutect2
- TRNT1 | c.879G>A p.V293= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as COSV51639802; called by muse, mutect2, varscan2
- TRPC4AP | c.726C>T p.L242= | Silent (SNP) | VAF 27/172 reads (16%) | catalogued as rs202043337; called by muse, mutect2, varscan2
- TSPO2 | c.204G>C p.L68= | Silent (SNP) | VAF 12/105 reads (11%) | catalogued as COSV55108930; called by muse, mutect2, varscan2
- TTC12 | c.807G>C p.L269= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV59096560; called by muse, mutect2, varscan2
- UBA1 | c.2052C>T p.P684= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV60111133; called by muse, mutect2, varscan2
- ULK1 | c.210G>A p.L70= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as rs371613349; called by muse, mutect2, varscan2
- UNKL | c.2052C>T p.I684= (on ENST00000389221 / NM_001372107.1; = p.I634= on NM_001193388.4) | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs750348181; called by muse, mutect2, varscan2
- UTRN | c.3555C>T p.L1185= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs1398852607, COSV62328446, COSV62329852; called by muse, mutect2, varscan2
- VIPR1 | c.948C>T p.I316= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV57296442; called by muse, mutect2, varscan2
- XPNPEP1 | c.1074C>T p.I358= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV59166616; called by muse, mutect2, varscan2
- ZBTB7A | c.1455C>T p.L485= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV59326148; called by muse, mutect2
- ZEB2 | c.783G>A p.V261= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as COSV57951214; called by muse, mutect2
- ZNF287 | c.684G>C p.V228= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV67688091; called by muse, mutect2, varscan2
- ZNF341 | c.2397G>A p.A799= (on ENST00000375200 / NM_001282935.1; = p.A792= on NM_032819.4) | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as rs548375525, COSV61005732; called by muse, mutect2, varscan2
- ZNF567 | c.1422G>A p.E474= (on ENST00000536254 / NM_001322913.1; = p.E443= on NM_152603.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 38/95 reads (40%) | catalogued as COSV62444134; called by muse, mutect2, varscan2
- BAX | c.474+85C>T | Intron (SNP) | VAF 31/72 reads (43%) | catalogued as COSV53168987; called by muse, varscan2
- BAX | c.474+146C>T | Intron (SNP) | VAF 44/97 reads (45%) | catalogued as COSV53168999; called by muse, varscan2
- BIRC8 | n.1468C>G | RNA (SNP) | VAF 25/259 reads (10%) | catalogued as COSV70346440; called by muse, mutect2, varscan2
- BMP1 | c.2108-659C>T | Intron (SNP) | VAF 23/138 reads (17%) | catalogued as rs145042921; called by muse, mutect2, varscan2
- FRMPD2B | n.873G>A | RNA (SNP) | VAF 26/261 reads (10%) | called by muse, mutect2
- MAPK8 | c.688+395C>T | Intron (SNP) | VAF 6/92 reads (7%) | catalogued as COSV64408306; called by muse, mutect2
- RPS6 | c.*1G>C | 3'UTR (SNP) | VAF 26/64 reads (41%) | catalogued as rs1012019872, COSV100194426, COSV59547721; called by muse, varscan2
- SNORD114-24 | n.7G>C | RNA (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- SON | c.6657+254C>T | Intron (SNP) | VAF 7/57 reads (12%) | catalogued as COSV51650371; called by muse, mutect2, varscan2
- TFE3 | c.*343G>A | 3'UTR (SNP) | VAF 26/49 reads (53%) | catalogued as rs782535682, COSV59948267; called by muse, mutect2, varscan2
- TTN | c.34265-5266G>T | Intron (SNP) | VAF 11/62 reads (18%) | catalogued as COSV59880741; called by muse, mutect2, varscan2
